Somatic mutation profile of tumor specimen TCGA-B5-A3FB-01A (aliquot TCGA-B5-A3FB-01A-11D-A19Y-09) from TCGA case TCGA-B5-A3FB, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 73.3 years (26,779 days).
Specimen TCGA-B5-A3FB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f38717f-f35c-4e9a-96a6-d84fce0f0840.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A3FB-10A (Blood Derived Normal), aliquot TCGA-B5-A3FB-10A-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e73bccaa-0f72-455b-b09f-8e788b87e0bd

The open-access MAF lists 54 somatic variants for this specimen: 36 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 31, Silent 18, Nonsense Mutation 2, In Frame Del 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.2424_2443del p.S809Gfs*15 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs574377079; called by mutect2, pindel, varscan2
- ADCY8 | c.2791G>T p.V931L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99650856; called by muse, mutect2, varscan2
- ANKRD35 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs180884834; called by muse, mutect2
- ARID1A | c.5296G>T p.E1766* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV61378533; called by muse, mutect2, varscan2
- BTK | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM950177, COSV58118855; called by muse, mutect2, varscan2
- CACFD1 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781883688, COSV99390096; called by muse, mutect2, varscan2
- CACNA1A | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100801062; called by muse, mutect2, varscan2
- DENND5A | c.2902G>T p.G968C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.95); catalogued as COSV100064103; called by muse, mutect2, varscan2
- DNAJA4 | c.333G>T p.Q111H (on ENST00000343789; = p.Q140H on NM_018602.3) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV100655119; called by muse, mutect2, varscan2
- ERC2 | c.126G>C p.K42N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV99881442; called by muse, mutect2, varscan2
- FAM111A | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs187676082; called by muse, mutect2, varscan2
- GJA8 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.606); catalogued as rs1272922415, COSV53788653; called by muse, mutect2, varscan2
- IL6ST | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as COSV100410646; called by muse, mutect2, varscan2
- KCNA1 | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV101230132; called by muse, mutect2
- LRCH2 | c.1163G>A p.S388N | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100406335; called by muse, mutect2, varscan2
- LRP1B | c.1692C>A p.H564Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV101253004, COSV67234180; called by muse, mutect2, varscan2
- MAP3K4 | c.4096G>A p.G1366R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815616, COSV62329900; called by muse, mutect2, varscan2
- MOB4 | c.479G>A p.C160Y | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99290935; called by muse, mutect2, varscan2
- MYH11 | c.5321C>T p.A1774V | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100257791; called by muse, mutect2, varscan2
- MYO5B | c.4021A>T p.R1341W | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99543724; called by muse, mutect2, varscan2
- NEK8 | c.1924C>T p.R642* | Nonsense Mutation (SNP) | VAF 26/42 reads (62%) | catalogued as rs763288569, COSV52046645; called by muse, mutect2, varscan2
- NEU4 | c.527C>T p.A176V (on ENST00000391969 / NM_001167602.3; = p.A188V on NM_080741.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100371828; called by muse, mutect2, varscan2
- NFASC | c.3106G>A p.G1036R | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.847); catalogued as rs748775050, COSV58376398; called by muse, mutect2, varscan2
- NOMO3 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99530675; called by muse, mutect2, varscan2
- OR12D3 | c.934T>A p.W312R | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV101011118; called by muse, mutect2, varscan2
- OR13H1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs376590984, COSV58547633; called by muse, mutect2, varscan2
- PAX1 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as rs747116290, COSV101270209; called by muse, mutect2, varscan2
- PLEKHM2 | c.1957G>A p.V653I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs746715478, COSV101009041; called by muse, mutect2, varscan2
- RBM24 | c.586G>A p.A196T (on ENST00000379052 / NM_001143942.2; = p.A151T on NM_153020.2) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs780198834, COSV100552841; called by muse, mutect2, varscan2
- RYR2 | c.8471G>A p.R2824Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as rs763223915, COSV100768188; called by muse, mutect2, varscan2
- SORT1 | c.1576A>G p.T526A | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99860504; called by muse, mutect2, varscan2
- TSKS | c.1370C>T p.S457L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs745342888, COSV55874087; called by muse, mutect2, varscan2
- DIP2B | c.1441+3del p.X481_splice | Splice Site (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- H2BC18 | c.362_370del p.K121_T123del | In Frame Del (DEL) | VAF 24/123 reads (20%) | called by mutect2, pindel, varscan2
- MROH5 | c.1250C>A p.T417N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); called by muse, mutect2
- ADGRB3 | c.3159C>A p.I1053= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99483737, COSV99486738; called by muse, mutect2, varscan2
- AKT1 | c.720C>T p.S240= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs1351020575, COSV100837973; called by muse, mutect2, varscan2
- BAX | c.435G>A p.R145= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs1568608647, COSV99508960; called by muse, mutect2, varscan2
- CDC27 | c.261A>G p.E87= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99293986; called by muse, mutect2, varscan2
- CDH4 | c.744C>T p.H248= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs753827955, COSV64659999; called by muse, mutect2, varscan2
- CORO7 | c.873C>T p.V291= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV99227233; called by muse, mutect2, varscan2
- EDA2R | c.141C>G p.R47= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV53633186, COSV99490526, COSV99490712; called by muse, mutect2, varscan2
- EIF4A1 | c.789A>G p.L263= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs540578884, COSV51512538; called by muse, mutect2, varscan2
- JADE3 | c.1068G>A p.V356= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99509556; called by muse, mutect2, varscan2
- LRP2 | c.3039C>T p.C1013= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs200245838, COSV99786679; called by muse, mutect2, varscan2
- NECTIN4 | c.303G>A p.P101= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs774994135, COSV100919822; called by muse, mutect2, varscan2
- OR5P3 | c.528C>T p.H176= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100103005; called by muse, mutect2, varscan2
- PNPLA6 | c.3678G>A p.P1226= (on ENST00000414982 / NM_001166111.2; = p.P1178= on NM_006702.5) | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs765541557, COSV55385672, COSV99654158; called by muse, mutect2, varscan2
- PPM1H | c.1191G>A p.L397= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs1302442007, COSV99955225; called by muse, mutect2, varscan2
- SKIDA1 | c.2673C>T p.G891= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV71610903, COSV71611106; called by muse, mutect2, varscan2
- SLC22A15 | c.507C>G p.R169= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV101047162; called by muse, mutect2, varscan2
- SLC26A5 | c.1326C>T p.A442= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV59705961; called by muse, mutect2, varscan2
- TMEM185A | c.453C>T p.L151= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as COSV100382945; called by muse, mutect2, varscan2
